Somatic mutation profile of tumor specimen TARGET-40-NAAWDT-01A (aliquot TARGET-40-NAAWDT-01A-01D) from TARGET case TARGET-40-NAAWDT, project TARGET-OS (Osteosarcoma). Sex at birth: female; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 26.0 years (9,490 days).
Specimen TARGET-40-NAAWDT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 683f55ec-c4dd-42ab-aab6-dfb7e8b51fa6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWDT-10A (Blood Derived Normal), aliquot TARGET-40-NAAWDT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d55a3abc-a1f1-4b45-82f3-6fece358f5b1

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK8 | c.3379A>T p.I1127L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GON4L | c.1467T>G p.S489R | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- SYNRG | c.1768del p.T590Lfs*19 | Frame Shift Del (DEL) | VAF 89/318 reads (28%) | called by mutect2, pindel, varscan2
- TTLL10 | c.1003C>T p.L335= (on ENST00000379289 / NM_001130045.2; = p.L262= on NM_153254.3) | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
